Somatic mutation profile of tumor specimen TCGA-50-5932-01A (aliquot TCGA-50-5932-01A-11D-1753-08) from TCGA case TCGA-50-5932, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 75.2 years (27,454 days).
Specimen TCGA-50-5932-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80fb6a60-988b-4237-82e1-3694c5dc1306.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5932-11A (Solid Tissue Normal), aliquot TCGA-50-5932-11A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d69f35d-6cb6-43a1-a62a-85344ac5ea7f

The open-access MAF lists 84 somatic variants for this specimen: 68 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 15, Nonsense Mutation 5, Frame Shift Del 4, Splice Site 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 16/36 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAM10 | c.2207G>T p.R736L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV53051065, COSV99545951; called by muse, mutect2, varscan2
- ADARB1 | c.1708G>T p.G570* (on ENST00000360697 / NM_001346687.2; = p.G530* on NM_001112.4) | Nonsense Mutation (SNP) | VAF 34/57 reads (60%) | catalogued as COSV62343801; called by muse, mutect2, varscan2
- ADGRV1 | c.9885G>T p.Q3295H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV67983591; called by muse, mutect2, varscan2
- ANK2 | c.90C>A p.D30E | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52157124; called by muse, mutect2, varscan2
- ANK2 | c.2751G>T p.R917S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV52157139; called by muse, mutect2, varscan2
- APOB | c.5444G>T p.R1815L | Missense Mutation (SNP) | VAF 87/229 reads (38%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.875); catalogued as COSV51932512; called by muse, mutect2, varscan2
- AQP12B | c.244C>A p.P82T (on ENST00000621682; = p.P94T on NM_001102467.2) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs769641721; called by muse, mutect2, varscan2
- ARHGAP32 | c.6152C>T p.P2051L (on ENST00000310343 / NM_001378025.1; = p.P1702L on NM_014715.4) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1401047908, COSV59846379; called by muse, mutect2, varscan2
- B4GALT6 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1300283261, COSV52703277, COSV52704188; called by muse, mutect2, varscan2
- BICRAL | c.1606G>T p.G536* | Nonsense Mutation (SNP) | VAF 42/77 reads (55%) | catalogued as COSV58404909, COSV58408018; called by muse, mutect2, varscan2
- C1orf94 | c.1053C>A p.S351R (on ENST00000488417 / NM_001134734.2; = p.S161R on NM_032884.5) | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV64913787; called by muse, mutect2, varscan2
- CBX2 | c.1232G>T p.S411I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV53968854; called by muse, mutect2
- CEP83 | c.586A>G p.N196D | Missense Mutation (SNP) | VAF 57/87 reads (66%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV60407867; called by muse, mutect2, varscan2
- CRX | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 28/37 reads (76%) | catalogued as COSV55757983; called by muse, mutect2, varscan2
- CWC27 | c.1099T>A p.Y367N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV66885484; called by muse, mutect2, varscan2
- DSG3 | c.2192C>A p.S731Y | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.61); catalogued as COSV57125688; called by muse, mutect2, varscan2
- EEF1A2 | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV53205771; called by muse, mutect2, varscan2
- EIF2AK4 | c.2710A>T p.T904S | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55467580; called by muse, mutect2, varscan2
- EPHA3 | c.1432C>A p.Q478K | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT tolerated (0.12); PolyPhen benign (0.138); catalogued as COSV60702276; called by muse, mutect2, varscan2
- FRAS1 | c.9463C>T p.Q3155* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV53605000; called by muse, mutect2, varscan2
- GRK5 | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs769347901, COSV64865548; called by muse, mutect2, varscan2
- H4C11 | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.963); catalogued as COSV100747958; called by muse, mutect2, varscan2
- IL6R | c.313A>T p.T105S | Missense Mutation (SNP) | VAF 42/60 reads (70%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV59816200; called by muse, mutect2, varscan2
- IPO8 | c.1783A>T p.S595C | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV56240995; called by muse, mutect2, varscan2
- ITGB8 | c.389-1G>T p.X130_splice | Splice Site (SNP) | VAF 41/118 reads (35%) | catalogued as COSV56007385; called by muse, mutect2, varscan2
- L3MBTL4 | c.548G>C p.S183T | Missense Mutation (SNP) | VAF 80/222 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV53120004; called by muse, varscan2
- MAGEC1 | c.2438C>T p.P813L | Missense Mutation (SNP) | VAF 113/176 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV53571155, COSV53571527; called by muse, mutect2, varscan2
- MC3R | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54763572; called by muse, mutect2
- MKI67 | c.6298A>G p.K2100E | Missense Mutation (SNP) | VAF 172/419 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.053); catalogued as COSV64073989; called by muse, mutect2, varscan2
- MKI67 | c.4811C>G p.S1604* | Nonsense Mutation (SNP) | VAF 80/209 reads (38%) | catalogued as COSV64073994; called by muse, mutect2, varscan2
- MUC16 | c.12362C>A p.T4121N | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.636); catalogued as COSV67461195; called by muse, mutect2, varscan2
- OR7E24 | c.521C>A p.S174Y | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV71702189; called by muse, mutect2, varscan2
- OTOGL | c.4181C>A p.A1394E (on ENST00000547103; = p.A1385E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT tolerated (0.36); PolyPhen benign (0.057); catalogued as rs1282727405, COSV101509051; called by muse, mutect2, varscan2
- PATJ | c.490G>T p.V164L | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs560787067, COSV57160417; called by muse, mutect2, varscan2
- PCDHGA3 | c.83C>A p.S28Y | Missense Mutation (SNP) | VAF 91/212 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.287); catalogued as COSV53895175, COSV53932691, COSV99542394; called by muse, mutect2, varscan2
- PSG11 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 134/226 reads (59%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as rs745836316, COSV60454820, COSV60457274; called by muse, mutect2
- PTPRD | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61939843; called by muse, mutect2, varscan2
- RIMS2 | c.1931G>T p.W644L (on ENST00000666250 / NM_001348490.2; = p.W452L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51674046; called by muse, mutect2, varscan2
- RUNX2 | c.1010G>T p.R337M | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV61840363; called by muse, mutect2, varscan2
- SF3B4 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54965164, COSV54966987; called by muse, mutect2, varscan2
- SLC13A3 | c.882G>T p.W294C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51714791; called by muse, mutect2, varscan2
- SOHLH2 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.054); catalogued as COSV58521623; called by muse, mutect2, varscan2
- SPATA18 | c.854G>A p.R285K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV54643831; called by muse, mutect2, varscan2
- SPATA5 | c.634A>T p.T212S | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV56774842; called by muse, mutect2, varscan2
- SREBF1 | c.1658A>G p.N553S | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs377727800; called by muse, mutect2, varscan2
- TAGAP | c.2074C>A p.L692I | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV57851322; called by muse, mutect2, varscan2
- TNN | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53425043, COSV99510721; called by mutect2, varscan2
- TRIO | c.2258C>T p.S753F | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60082196; called by muse, mutect2, varscan2
- TTC21B | c.3016C>T p.P1006S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV54629763; called by muse, mutect2, varscan2
- UGT2B4 | c.423G>T p.Q141H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV59316664; called by muse, mutect2, varscan2
- VHLL | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.01); catalogued as rs1465122790; called by muse, mutect2, varscan2
- VPS13B | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV62018468; called by muse, mutect2, varscan2
- VPS16 | c.994+1G>T p.X332_splice | Splice Site (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100988349; called by mutect2, varscan2
- AQP12B | c.245C>A p.P82H (on ENST00000621682; = p.P94H on NM_001102467.2) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CAPN6 | c.846_856del p.R283Gfs*11 | Frame Shift Del (DEL) | VAF 50/285 reads (18%) | called by mutect2, pindel, varscan2
- IGHA1 | c.947G>C p.G316A | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- KCNA5 | c.842T>A p.L281Q | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2
- MRGPRX1 | c.12del p.I5Sfs*8 | Frame Shift Del (DEL) | VAF 92/292 reads (32%) | called by mutect2, pindel, varscan2
- SPATA6 | c.1296_1308del p.Q433Lfs*61 | Frame Shift Del (DEL) | VAF 35/120 reads (29%) | called by mutect2, pindel, varscan2
- TFDP1 | c.915G>T p.M305I | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- TFDP1 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- TLK1 | c.1905-4_1912del p.X635_splice | Splice Site (DEL) | VAF 62/174 reads (36%) | called by mutect2, pindel
- TMEM53 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TTLL9 | c.660A>G p.I220M | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- ZBED4 | c.375del p.F125Lfs*16 | Frame Shift Del (DEL) | VAF 19/37 reads (51%) | called by mutect2, pindel, varscan2
- ZNF276 | c.1138G>T p.D380Y (on ENST00000443381 / NM_001113525.2; = p.D305Y on NM_152287.4) | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF789 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- ABCC2 | c.1071G>A p.L357= | Silent (SNP) | VAF 182/426 reads (43%) | catalogued as COSV64970780, COSV64971281; called by muse, mutect2, varscan2
- ADCY9 | c.1758C>T p.A586= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs1006530209, COSV53574290; called by muse, mutect2, varscan2
- ATP6AP1 | c.702C>T p.A234= | Silent (SNP) | VAF 3/51 reads (6%) | catalogued as rs138051216, COSV63895585; called by muse, mutect2
- GSAP | c.2046G>A p.R682= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs1183917220, COSV57529446; called by muse, mutect2, varscan2
- KCNA5 | c.841C>T p.L281= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as rs1370196044, COSV52908562; called by muse, mutect2
- MTMR14 | c.372G>T p.R124= | Silent (SNP) | VAF 20/27 reads (74%) | catalogued as COSV56004487; called by muse, mutect2, varscan2
- OXTR | c.495G>A p.L165= | Silent (SNP) | VAF 10/11 reads (91%) | catalogued as rs1035086952, COSV57479022; called by muse, mutect2, varscan2
- PDE1C | c.999A>T p.V333= | Silent (SNP) | VAF 111/276 reads (40%) | catalogued as COSV58511377, COSV58515291; called by muse, mutect2, varscan2
- PHKG1 | c.675C>A p.A225= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV51916174; called by muse, mutect2, varscan2
- PLB1 | c.261G>A p.T87= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs534234691, COSV100577387, COSV59823416; called by muse, mutect2, varscan2
- PXDN | c.3447G>A p.T1149= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as rs1285433649, COSV53231865, COSV53248558; called by muse, mutect2, varscan2
- RYR2 | c.5115G>T p.L1705= | Silent (SNP) | VAF 68/95 reads (72%) | catalogued as COSV100773426, COSV63680243; called by muse, mutect2, varscan2
- SLC66A2 | c.555G>T p.L185= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV60842925; called by muse, mutect2, varscan2
- SNED1 | c.3492G>A p.L1164= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV60022746; called by muse, mutect2, varscan2
- VWA1 | c.513C>A p.G171= | Silent (SNP) | VAF 17/22 reads (77%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506187 ins T | 3'Flank (INS) | VAF 21/76 reads (28%) | catalogued as rs750740790; called by mutect2, pindel, varscan2
